Somatic mutation profile of tumor specimen TCGA-IG-A3YA-01A (aliquot TCGA-IG-A3YA-01A-11D-A247-09) from TCGA case TCGA-IG-A3YA, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.6 years (19,567 days).
Specimen TCGA-IG-A3YA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9608092-909d-4b0f-9db8-efe96c3f77e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3YA-10A (Blood Derived Normal), aliquot TCGA-IG-A3YA-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f0de9f-bdd4-46a5-8553-9b7f912cc049

The open-access MAF lists 79 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Nonsense Mutation 5, RNA 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANO1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100304372, COSV100304621; called by muse, mutect2, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2, varscan2
- CDK5R1 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs769214004, COSV100531933; called by mutect2, varscan2
- DMRTB1 | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.701); catalogued as rs150466113; called by muse, mutect2
- EGFL6 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100789868; called by muse, mutect2
- FAM47C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1556332457, COSV63725336; called by muse, mutect2, varscan2
- FAT4 | c.9763C>T p.Q3255* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100627472, COSV58698755; called by muse, mutect2, varscan2
- FLOT2 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs376860005; called by muse, mutect2, varscan2
- KIFC1 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs112635529, COSV104423932; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by mutect2, varscan2
- LZTS3 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV61278243; called by muse, mutect2, varscan2
- MARF1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); catalogued as rs1162083192, COSV100706388; called by muse, mutect2, varscan2
- MBD5 | c.2969A>G p.Q990R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs1429975125; called by muse, mutect2, varscan2
- MGAT4C | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59831256; called by muse, mutect2, varscan2
- MMP14 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs554056813; called by muse, mutect2, varscan2
- MYH13 | c.5546G>A p.R1849H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52823708; called by muse, mutect2, varscan2
- MYH7 | c.4423C>T p.R1475C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139646545, CM050711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T2 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1488979169; called by muse, mutect2, varscan2
- OTUD7B | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs782204756, COSV64915963; called by muse, mutect2, varscan2
- PCSK5 | c.3575G>T p.G1192V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1232456025; called by muse, mutect2
- RBBP8 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091014; called by muse, mutect2, varscan2
- SATL1 | c.955C>G p.L319V (on ENST00000395409; = p.L506V on NM_001012980.2) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as rs762180135; called by muse, mutect2, varscan2
- SUPT6H | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58924997; called by muse, mutect2
- TAF5L | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs973230338; called by muse, mutect2, varscan2
- TEX101 | c.169G>T p.G57W (on ENST00000598265 / NM_001130011.3; = p.G75W on NM_031451.4) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV53662140; called by muse, mutect2
- TRANK1 | c.7365G>C p.E2455D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57144169; called by muse, mutect2, varscan2
- ZNF212 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs774957598; called by muse, mutect2, varscan2
- ABCB6 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); called by muse, varscan2
- ACADVL | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRWD3 | c.4051G>C p.E1351Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CHD4 | c.1647G>A p.Q549= (on ENST00000357008 / NM_001363606.2; = p.Q562= on NM_001273.5) | Splice Region (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.951A>T p.K317N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND10 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- ELAPOR2 | c.1001A>G p.E334G (on ENST00000450689 / NM_001142749.3; = p.E167G on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN1 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- FLG | c.4942G>C p.E1648Q | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRMPD2 | c.1014T>G p.Y338* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- GALR2 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.272); called by mutect2, varscan2
- GRM8 | c.1984A>C p.S662R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGSF3 | c.1784T>A p.L595* (on ENST00000369486 / NM_001007237.3; = p.L615* on NM_001542.4) | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- KRT25 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LSM7 | c.55A>T p.I19F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- LSM7 | c.54C>A p.Y18* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NEUROD6 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.266); called by muse, mutect2
- NOMO1 | c.3577G>T p.G1193* | Nonsense Mutation (SNP) | VAF 17/399 reads (4%) | called by muse, mutect2
- PRSS22 | c.374G>C p.W125S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RPL8 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2
- SLTM | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TNPO3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- TNXB | c.10454A>G p.H3485R (on ENST00000647633; = p.H3238R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TOMM34 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSPYL5 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TTN | c.95692G>C p.D31898H (on ENST00000591111; = p.D24474H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- TXNDC16 | c.2317G>T p.V773L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5A | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- XDH | c.970A>C p.T324P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZFP14 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ZNF536 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.4951C>A p.L1651M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADRA1A | c.750C>T p.S250= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV52374261; called by muse, mutect2, varscan2
- AVIL | c.723C>A p.I241= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs547034263, COSV57682633; called by muse, mutect2, varscan2
- CERCAM | c.744C>T p.F248= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs142843167; called by muse, mutect2, varscan2
- GLA | c.543A>G p.A181= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- HRNR | c.57C>A p.A19= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1220124081, COSV100913703; called by muse, mutect2
- KCND2 | c.15G>A p.V5= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100478963; called by muse, mutect2, varscan2
- KIF17 | c.2673C>T p.G891= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs764516097; called by muse, mutect2, varscan2
- KRT34 | c.189C>T p.C63= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs374587752; called by muse, mutect2, varscan2
- MASTL | c.1494T>C p.S498= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.24201A>G p.G8067= | Silent (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- NOS1 | c.1980C>T p.T660= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs765418769; called by muse, mutect2
- OLFM3 | c.783T>A p.T261= (on ENST00000338858 / NM_001288821.1; = p.T241= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- ROCK2 | c.2175C>T p.I725= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs770615625; called by muse, mutect2, varscan2
- TSPYL4 | c.822C>T p.D274= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- VPS13A | c.8775C>T p.T2925= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs200321658, COSV100653223; called by muse, mutect2, varscan2
- MIR1197 | n.15G>A | RNA (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- MIR518D | n.2C>A | RNA (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 10/98 reads (10%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2
